Somatic mutation profile of tumor specimen C3N-03038-02 (aliquot CPT0235090006) from CPTAC case C3N-03038, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; Tumor grade: G2.
Specimen C3N-03038-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 13c2218d-654b-46f3-9288-4119301ed844.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03038-71 (Blood Derived Normal), aliquot CPT0235210002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fd1f0404-92af-43d2-b34d-58c409e76c1e

The open-access MAF lists 26 somatic variants for this specimen: 20 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 4, Frame Shift Del 2, Splice Site 1, Nonsense Mutation 1, Frame Shift Ins 1, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 38/314 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- SF3B1 | c.2098A>G p.K700E | Missense Mutation (SNP) | VAF 8/75 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs559063155, COSV59205318, COSV59216586; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CAST | c.728C>T p.S243L (on ENST00000341926; = p.S326L on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/272 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs777835139; called by muse, mutect2, varscan2
- CIC | c.687del p.V230Sfs*27 | Frame Shift Del (DEL) | VAF 45/383 reads (12%) | catalogued as COSV50548746; called by mutect2, pindel, varscan2
- CSF2RB | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 26/239 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.044); catalogued as rs1333046023; called by muse, mutect2, varscan2
- GPR162 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 29/277 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1231088025, COSV50590523; called by muse, mutect2, varscan2
- KIF1A | c.3008G>A p.R1003H | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100242861; called by muse, mutect2
- MDN1 | c.6902G>A p.R2301Q | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65526332; called by muse, mutect2
- NBPF14 | c.3493A>T p.I1165F | Missense Mutation (SNP) | VAF 4/434 reads (1%) | SIFT tolerated (0.07); PolyPhen benign (0.249); catalogued as rs1443396976; called by muse, mutect2
- NKX2-1 | c.229C>T p.Q77* | Nonsense Mutation (SNP) | VAF 31/335 reads (9%) | catalogued as CM1314552; called by muse, mutect2
- TAP1 | c.1942C>A p.P648T | Missense Mutation (SNP) | VAF 46/426 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62755163; called by muse, mutect2, varscan2
- TKFC | c.562A>G p.M188V | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as rs750874385; called by muse, mutect2, varscan2
- ASCC3 | c.2602A>G p.T868A | Missense Mutation (SNP) | VAF 49/515 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CACNA2D1 | c.575T>A p.V192D | Missense Mutation (SNP) | VAF 49/428 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- CEP135 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- COL17A1 | c.3013G>C p.G1005R | Missense Mutation (SNP) | VAF 54/550 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- HENMT1 | c.491A>T p.N164I | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- KDM6A | c.2974_2981del p.A992* | Frame Shift Del (DEL) | VAF 25/126 reads (20%) | called by pindel, varscan2*
- LYRM1 | c.221dup p.L75Tfs*45 | Frame Shift Ins (INS) | VAF 30/194 reads (15%) | called by mutect2, pindel, varscan2
- NDUFB9 | c.408+2T>C p.X136_splice | Splice Site (SNP) | VAF 42/235 reads (18%) | called by muse, mutect2, varscan2
- CNGA3 | c.1860C>T p.G620= | Silent (SNP) | VAF 73/769 reads (9%) | catalogued as rs529873704, COSV55629287; called by muse, mutect2, varscan2
- COL16A1 | c.1024C>A p.R342= | Silent (SNP) | VAF 23/202 reads (11%) | catalogued as COSV99594337; called by muse, mutect2, varscan2
- MYH7 | c.3135C>T p.R1045= | Silent (SNP) | VAF 39/336 reads (12%) | catalogued as COSV100806406; called by muse, mutect2, varscan2
- SERPINB4 | c.840C>T p.V280= | Silent (SNP) | VAF 14/213 reads (7%) | catalogued as rs755293512; called by muse, mutect2
- ODF3B | c.*7_*20del | 3'UTR (DEL) | VAF 22/232 reads (9%) | catalogued as rs781283572; called by mutect2, pindel
- UCKL1 | c.924-107G>A | Intron (SNP) | VAF 6/38 reads (16%) | catalogued as rs943520562; called by muse, mutect2, varscan2
